Somatic mutation profile of tumor specimen TCGA-30-1862-01A (aliquot TCGA-30-1862-01A-02W-0699-08) from TCGA case TCGA-30-1862, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 65.4 years (23,895 days).
Specimen TCGA-30-1862-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d633f9f0-381c-4455-b42c-7a71b35f3903.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-30-1862-10A (Blood Derived Normal), aliquot TCGA-30-1862-10A-01W-0699-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e55a182c-d03a-4751-8c29-b0388b340dd7

The open-access MAF lists 38 somatic variants for this specimen: 32 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 25, Silent 6, Nonsense Mutation 4, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.5357C>A p.S1786* (on ENST00000358273 / NM_001042492.3; = p.S1765* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 63/116 reads (54%) | catalogued as rs1555533569, CS001442, COSV62198764, COSV62222750; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.672+1G>A p.X224_splice | Splice Site (SNP) | VAF 77/107 reads (72%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABCF2 | c.1509C>G p.Y503* | Nonsense Mutation (SNP) | VAF 167/864 reads (19%) | catalogued as COSV55180959, COSV55182167; called by muse, mutect2, varscan2
- ACACB | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1355122797, COSV58131542; called by mutect2, varscan2
- ALG10B | c.79T>A p.F27I | Missense Mutation (SNP) | VAF 87/233 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58142849; called by muse, mutect2, varscan2
- ATAD2 | c.1744C>A p.P582T | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54879365; called by muse, mutect2, varscan2
- CACNA1A | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 344/1250 reads (28%) | catalogued as COSV64194496; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1248-2A>T p.X416_splice (on ENST00000357886 / NM_001365728.1; = p.X402_splice on NM_016082.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 49/224 reads (22%) | catalogued as rs780260019, COSV59426437; called by muse, mutect2, varscan2
- CSMD3 | c.5816G>C p.C1939S (on ENST00000297405 / NM_001363185.1; = p.C1835S on NM_052900.3) | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52145731; called by muse, mutect2, varscan2
- EPHB6 | c.108G>T p.L36F | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753392889, COSV67418008; called by muse, mutect2, varscan2
- EYA1 | c.1009C>T p.H337Y | Missense Mutation (SNP) | VAF 91/353 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100379937, COSV58160087; called by muse, mutect2, varscan2
- GABPA | c.242T>C p.L81S | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61395870; called by muse, mutect2, varscan2
- GPRC6A | c.1283A>G p.D428G | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV59952395; called by muse, mutect2, varscan2
- HSPA2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs969625689, COSV55969196; called by muse, mutect2, varscan2
- LRRC4B | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs921384119, COSV100975854; called by muse, mutect2
- LZTS2 | c.615T>A p.F205L | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64651347; called by muse, mutect2, varscan2
- MIGA1 | c.941G>T p.G314V | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.129); catalogued as COSV66223300; called by muse, mutect2, varscan2
- MS4A8 | c.312C>G p.Y104* | Nonsense Mutation (SNP) | VAF 157/805 reads (20%) | catalogued as COSV55753762; called by muse, mutect2, varscan2
- NFKBIL1 | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV100385357; called by muse, mutect2, varscan2
- OR6K3 | c.439C>T p.R147C (on ENST00000368146; = p.R131C on NM_001005327.2) | Missense Mutation (SNP) | VAF 90/490 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs748128044, COSV63745210; called by muse, mutect2, varscan2
- PCDHA5 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.587); catalogued as rs1489857640, COSV65349480; called by muse, mutect2, varscan2
- PLEKHG1 | c.371C>A p.T124N | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62046456, COSV62051207; called by muse, mutect2, varscan2
- PRKD1 | c.1429G>A p.V477I | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV59563923; called by muse, mutect2, varscan2
- TAOK1 | c.2578C>T p.R860C | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1567750713, COSV55590253; called by muse, mutect2, varscan2
- TCHHL1 | c.707A>C p.D236A | Missense Mutation (SNP) | VAF 108/486 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.066); catalogued as COSV64285375; called by muse, mutect2, varscan2
- TMEM63C | c.2019C>G p.F673L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53602703; called by muse, mutect2
- TOP2A | c.4417G>T p.D1473Y | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); catalogued as COSV68503019; called by muse, mutect2, varscan2
- TPP2 | c.3736T>G p.Y1246D | Missense Mutation (SNP) | VAF 154/301 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV65751996; called by muse, mutect2, varscan2
- TRPC7 | c.1496C>G p.A499G | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.33); catalogued as COSV100725545; called by muse, varscan2
- UBR5 | c.1037A>G p.K346R | Missense Mutation (SNP) | VAF 344/661 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as rs767658152, COSV55283942; called by muse, mutect2, varscan2
- CNNM1 | c.2207T>G p.L736W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- KIAA0513 | c.741dup p.L248Afs*66 | Frame Shift Ins (INS) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- FAT2 | c.11742T>C p.D3914= | Silent (SNP) | VAF 114/303 reads (38%) | catalogued as COSV55816871; called by muse, mutect2, varscan2
- GRIP2 | c.1497C>G p.S499= (on ENST00000619221; = p.S402= on NM_001080423.4) | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV99817031; called by muse, mutect2, varscan2
- MED12L | c.1989A>G p.G663= | Silent (SNP) | VAF 74/111 reads (67%) | catalogued as COSV56374586; called by muse, mutect2, varscan2
- OVCH1 | c.1191A>G p.E397= | Silent (SNP) | VAF 116/367 reads (32%) | catalogued as rs373966834, COSV58961473; called by muse, mutect2, varscan2
- SDK1 | c.2640C>T p.A880= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs765233530, COSV67363024; called by muse, mutect2, varscan2
- USP25 | c.1476A>G p.E492= | Silent (SNP) | VAF 67/276 reads (24%) | catalogued as COSV53482928; called by muse, mutect2, varscan2
